Gene-level copy-number profile of tumor specimen ALCH-B1YT-TTP1-A from ALCHEMIST case ALCH-B1YT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.3 years (19,849 days).
Specimen ALCH-B1YT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5b078b97-8d7d-4170-a2f3-5dfd19978e31.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1YT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/874a0728-cd42-41c6-b993-72fc927addbc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 906; copy number 2: 57,214; copy number 3: 235; copy number 4: 6; copy number 5: 1; copy number 6: 5; copy number 7: 2; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:124,395,534–124,399,024, 1 gene: OR8B3.
- chr16:649,311–768,865, 19 genes (within-gene range 0–1): WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN.
- chr16:89,166,383–89,169,147, 1 gene: LINC02138.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:86,907,953–87,013,976, 3 genes, copy number 8 (within-gene range 2–8): RGPD1, WBP1P1, NDUFB4P5.
- chr16:32,356,981–32,380,049, 2 genes, copy number 7: AC133548.1, ACTR3BP3.
- chr16:32,635,673–32,678,831, 6 genes, copy number 5–6: AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.

Autosomal genes at a single copy (total copy number 1): 906. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
